Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GD, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GD-06A (Metastatic).

[page 1 of 2]
ICD 0.3
Melanoma NOS 8720/3
Site: Inguinal lymph node
2724
9/21/27/13

DIAGNOSIS

A) RIGHT INGUINAL CONTENTS, LYMPH NODE DISSECTION:

METASTATIC MELANOMA INVOLVING AT LEAST FIVE OF NINE LYMPH NODES (5/9). (SEE COMMENT)

Largest tumor deposit size: 70 x 40 x 30 mm (per gross description).

Location: Subcapsular and intraparenchymal.

EXTRACAPSULAR EXTENSION: PRESENT.

Skin and subcutaneous tissue with changes consistent with previous biopsy/surgical procedure site.

B) RIGHT ILIAC AND OBTURATOR CONTENTS, LYMPH NODE DISSECTION:

METASTATIC MELANOMA INVOLVING ONE OF ELEVEN LYMPH NODES (1/11). (SEE COMMENT)

Largest tumor deposit size: 45 x 42 x 25 mm (per gross description).

Location: Subcapsular and intraparenchymal.

EXTRACAPSULAR EXTENSION: PRESENT.

C) RIGHT LATERAL KNEE, SKIN ELLIPSE:

Skin and subcutaneous tissue with changes consistent with healing surgical wound and scar.

Associated residual melanoma not identified. Margins have been evaluated.

METASTATIC MELANOMA INVOLVING DERMIS AND SUBCUTANEOUS SOFT TISSUE, INKED TISSUE EDGES
APPEAR FREE. (SEE COMMENT)

TUMOR SIZE: 8 X 6 X 6 MM (PER GROSS DESCRIPTION).

Tumor borders predominantly pushing.

Associated focal lymphoid tissue is present.

Multiple incidental macular seborrheic keratoses, some irritated, some present at inked tissue edges.

Solar elastosis and actinic changes.

Folliculitis.

Stasis changes.

COMMENT

(A-C) The tumor cells in each part above demonstrate prominent cherry-red nucleoli and scattered intranuclear pseudoinclusions, and they have similar (epithelioid) morphology as the patient's known melanoma involving the right leg (see case _____). In parts (A) and (B), focal intracytoplasmic melanin pigment is identified, and in part (A), tumor necrosis is seen. These findings altogether support the above diagnoses of melanoma.

In part (A), the largest tumor masses may each represent one lymph node which has become replaced by metastatic tumor or multiple matted lymph nodes which have become replaced by tumor. Clinical – pathologic correlation is necessary.

In part (C), residual melanoma associated with the changes of healing surgical wound and scar is not identified. There is a separate focus of melanoma involving the dermis and subcutaneous soft tissue. No overlying in situ component or direct connection by the tumor with the epidermis is seen. Associated focal lymphoid tissue is present. This tumor may represent a metastasis/satellite lesion involving the dermis and subcutaneous fibroadipose tissue or a lymph node which has become replaced by metastatic tumor. Clinical – pathologic correlation is necessary. In the sections submitted for permanent section evaluation, the inked tissue edges appear free of this focus of melanoma.

GROSS DESCRIPTION

(A) RIGHT INGUINAL CONTENTS – One portion of fibroadipose tissue (26.0 x 10.0 x 4.0 cm) with overlying ellipse of pink-tan skin (22.0 x 2.0 cm). The skin appears grossly unremarkable. The specimen is serially sectioned to reveal four separate tumor nodules involving subcutaneous tissue that range from 3.0 x 3.0 x 3.0 cm up to 7.0 x 4.0 x 3.0 cm. Several of these nodules may each represent one or several lymph nodes which have become replaced by tumor. Multiple additional possible lymph nodes are dissected from the specimen that measure from 0.3 x 0.3 x 0.3 cm up to 1.0 x 0.8 x 0.8 cm. Portions of the two largest tumor nodules are submitted to the tissue bank for research purposes, and representative sections of these nodules as well as all possible lymph nodes are submitted for permanent section evaluation in A.

[page 2 of 2]
SECTION CODE: A1, A2, representative sections of largest tumor nodule; A3, A4, representative sections of second largest tumor nodule; A5, representative sections of third tumor nodule; A6, representative sections of fourth tumor nodule; A7, three possible lymph nodes; A8, four possible lymph nodes; A9-A11, additional possible lymph nodes; A12, representative section of skin with subcutaneous tissue; A13, A14, each five possible lymph nodes; A15, four possible lymph nodes; A16, three possible lymph nodes; A17, one possible lymph node, bisected.

(B) RIGHT ILIAC AND OBTURATOR CONTENTS – Multiple portions of fibroadipose tissue (8.0 x 7.0 x 5.0 cm in aggregate), from which multiple possible lymph nodes are dissected that measure from 0.4 x 0.4 x 0.4 cm up to 6.5 x 1.5 x 1.0 cm. There is a firm, tan tumor nodule identified (4.5 x 4.2 x 2.5 cm) that may represent a lymph node which has become replaced by tumor. A portion of the tumor nodule is submitted to the tissue bank for research purposes, and representative sections of this nodule as well as all possible lymph nodes are submitted for permanent section evaluation in B.

SECTION CODE: B1, B2, representative sections of tumor nodule; B3, B4, each four possible lymph nodes; B5, one possible lymph node, bisected; B6, one possible lymph node, serially sectioned; B7-B9, one possible lymph node, serially sectioned.

(C) 2 CM MARGIN, MELANOMA, RIGHT LATERAL KNEE WITH RESECTION IN TRANSIT NODULE, SHORT – PROXIMAL 12 O'CLOCK, LONG – INFERIOR 3 O'CLOCK – An ellipse of pink-tan skin with underlying subcutaneous tissue (11.0 x 5.0 x 2.0 cm), which is oriented by the surgeon with a short suture stitch to denote proximal 12 o'clock and a long stitch to denote inferior 3 o'clock. Centrally located on the surface of the skin is a linear, well-healed scar (7.0 cm in length) that measures 1.8 cm from the 6 o'clock tissue edge and 2.0 cm from the 12 o'clock, 3 o'clock, and 9 o'clock tissue edges. The specimen is inked and serially sectioned to reveal a separate tumor nodule (0.8 x 0.6 x 0.6 cm) within the proximal half of the specimen that measures 1.5 cm from the nearest 9 o'clock tissue edge and 1.4 cm from the scar. Half of this tumor nodule is submitted to the tissue bank for research purposes. The remaining portion of the nodule as well as the entire area of scar (the latter en bloc) are submitted for permanent section evaluation in C.

INK CODE: Blue – 12-3-6 o'clock half; yellow – 6-9-12 o'clock half; green - 3 o'clock side of en bloc area of scar (for orientation purposes, not a margin).

SECTION CODE: C1, the tumor nodule relative to nearest 9 o'clock tissue edge, perpendicular section; C2, nearest deep tissue edge underlying tumor nodule; C3, skin and subcutaneous tissue relative to tumor nodule and deep tissue edge, perpendicular section; C4, 12 o'clock tissue edge, inked side up; C5, 6 o'clock tissue edge, inked side up; C6, 3 o'clock tissue edge, proximal half, inked side up; C7, 3 o'clock tissue edge, distal half, inked side up; C8, 9 o'clock tissue edge, proximal half, inked side up; C9, 9 o'clock tissue edge, distal half, inked side up; C10, skin and subcutaneous tissue proximal to scar; C11-C18, the area of scar, entirely submitted from proximal to distal; C19, skin and subcutaneous tissue distal to scar.

BIOMARKER TESTING

Blocks A1-A6, B1, B2.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

T-C4000, T-C4800, T-02820, M-87206, M-78060

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

HPV AA Discrepancy		✓

Source: NCI Genomic Data Commons file f496def0-33dc-48f8-bc49-d415727dee5e (TCGA-D3-A8GD.394D0E1F-21DE-45BB-9D03-AB9326D95BA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).